Gene-level copy-number profile of tumor specimen TCGA-73-4668-01A from TCGA case TCGA-73-4668, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Invasive micropapillary carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.4 years (24,255 days).
Specimen TCGA-73-4668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7de1a471-973a-4b31-8f61-38b7c9bcc74a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-73-4668-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/19e7b375-1179-422a-92e7-49d918d1ca73

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 440; copy number 2: 18,402; copy number 3: 18,518; copy number 4: 14,865; copy number 5: 3,770; copy number 6: 3,392; copy number 7: 127; copy number 8: 158; copy number 9: 21; copy number 11: 6; copy number 14: 20; copy number 17: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-73-4668-01A-01D-1204-01): tumor purity 0.53, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,453,209–24,592,104, 92 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 340 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:96,760,902–97,739,862, 46 genes, copy number 8 (within-gene range 4–8): CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P, ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70.
- chr3:61,561,569–63,203,448, 16 genes, copy number 9–17: PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3.
- chr5:18,886,622–31,329,146, 115 genes, copy number 7 (broad region; genes not listed).
- chr9:35,360,540–35,736,999, 26 genes, copy number 8: AL160274.1, ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853.
- chr10:48,306,639–49,188,585, 20 genes, copy number 8–11 (within-gene range 2–11): MAPK8, AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1, AC068898.2, AC068898.1, WDFY4, RPL13AP19, AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4, FAM170B-AS1, FAM170B, TMEM273.
- chr12:24,212,421–25,250,936, 22 genes, copy number 8–14: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:26,905,181–28,581,511, 42 genes, copy number 8 (within-gene range 3–8): INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355.
- chr13:18,467,172–18,734,896, 12 genes, copy number 7: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P.
- chr17:15,229,773–15,908,632, 41 genes, copy number 8 (within-gene range 2–8): PMP22, MIR4731, AC005703.5, AC005703.2, AC005703.6, AC005703.1, TEKT3, RNU6-799P, AC005703.4, AC005703.3, RN7SL792P, CDRT4, TVP23C-CDRT4, RPL9P2, TVP23C, PPIAP53, AC005838.2, CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1.

Autosomal genes at a single copy (total copy number 1): 182. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
